Gene-level copy-number profile of tumor specimen TCGA-DX-A6Z0-01A from TCGA case TCGA-DX-A6Z0, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 78.8 years (28,796 days).
Specimen TCGA-DX-A6Z0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.d05c9382-f7d9-42db-8a39-84a11713317c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6Z0-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/abe8bdce-efc7-479d-a868-fc56372078b2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 118; copy number 1: 530; copy number 2: 10,892; copy number 3: 23,087; copy number 4: 14,965; copy number 5: 4,254; copy number 6: 2,894; copy number 7: 517; copy number 8: 1,008; copy number 9: 774; copy number 10: 362; copy number 11: 363; copy number 12: 9; copy number 13: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6Z0-01A-13D-A36I-01): tumor purity 0.57, ploidy 3.39, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–27,230,174, 99 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:27,284,654–29,318,952, 19 genes: EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,309 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:6,839,460–7,219,291, 1 gene, copy number 12 (within-gene range 3–12): LINC02196.
- chr5:7,047,227–7,326,609, 8 genes, copy number 12: RNA5SP176, AC025756.1, AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1.
- chr5:12,914,068–28,809,291, 185 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr5:42,423,439–42,721,878, 1 gene, copy number 7 (within-gene range 6–7): GHR.
- chr5:42,729,138–45,895,970, 58 genes, copy number 7: AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr5:51,438,792–51,665,048, 1 gene, copy number 7 (within-gene range 5–7): AC022433.1.
- chr5:51,886,688–52,282,859, 5 genes, copy number 7: RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11.
- chr6:108,798,929–170,553,307, 972 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr7:52,493,152–69,430,923, 391 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr11:123,805,335–123,977,781, 8 genes, copy number 7: OR6M1, OR6M2P, OR6M3P, TMEM225, OR8D4, OR4D5, OR6T1, OR10S1.
- chr19:27,638,483–38,383,824, 365 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr19:39,125,770–44,931,386, 314 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 530. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
